Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7924, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7924-01A (Primary Tumor).

[page 1 of 7]
Patient Results

Final

Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. : [REDACTED]

Final Diagnosis(es):

(A) Liver biopsy:

1) Mild mixed portal inflammation with focal bile duct proliferation.

2) Mild portal expansion by fibrosis with focal fibrous septa.

3) Negative for malignancy.

(B) Left tube and ovary, salpingo-oophorectomy:

1) Ovary with dermoid cyst.

2) Fallopian tube with endosalpingiosis

3) Negative for malignancy.

(C) Falciform ligament, biopsy:

1) Benign fibrovascular and adipose tissue.

2) Negative for malignancy.

(D) Peritoneal mass, biopsy:

1) Hyalinized nodule with dystrophic calcification.

2) Negative for malignancy.

(E) Lymph nodes, hepatoduodenal area, biopsy: Five lymph nodes, negative for malignancy (0/5).

(F) Lymph node, portal area, biopsy: One lymph node, negative for malignancy (0/1).

(G) Lymph node, posterior portal area, biopsy: One lymph node, negative for malignancy (0/1).

(H) Lymph nodes, anterior portal area, biopsy: Two lymph nodes, negative for malignancy (0/2).

(I) Common bile duct, biopsy: Negative for malignancy.

(J) Pancreatic margin, biopsy: Positive for pancreatic adenocarcinoma.

(K) Pancreas, distal stomach, duodenum, gallbladder, common bile duct, Whipple's resection:

1) Invasive pancreatic adenocarcinoma, moderately differentiated.

2) The tumor measures 5.0 cm in greatest dimension.

3) The surgical margins are negative for involvement by malignancy.

4) Eight lymph nodes, negative for malignancy (0/8).

4) Pathologic staging: pT3N0.

5) See Synoptic Report below.

(L) Pancreatic margin, new, biopsy:

1) Atypical focus of glandular epithelium.

2) Extensive chronic pancreatitis.

(M) Pancreas, distal, resection:

1) Invasive pancreatic adenocarcinoma, moderately differentiated.

Printed from: Default

Page: 1 of 7

[page 2 of 7]
[REDACTED] R

Patient Results

[REDACTED]

[REDACTED] Final

2) Extensive chronic pancreatitis.

Synoptic Report:

Specimen:

Head of pancreas.

Body of pancreas.

Tail of pancreas.

Duodenum.

Stomach, distal.

Common bile duct.

Gallbladder.

Procedure: Pancreaticoduodenectomy (Whipple's resection), total pancreatectomy.

Tumor Site: Pancreatic head.

Tumor Size:

Greatest Dimension: 5 cm.

Additional Dimensions: 5 x 4.5 cm.

Histologic Type: Ductal adenocarcinoma.

Histologic Grade: G2: Moderately differentiated.

Microscopic Tumor Extension:

Tumor invades ampulla of Vater.

Tumor invades duodenal wall.

Tumor invades peripancreatic soft tissues.

Margins: Margins uninvolved by invasive carcinoma.

Lymphovascular Invasion: Not identified.

Perineural Invasion: Identified.

Pathologic Staging:

Primary Tumor: pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery.

Regional Lymph Nodes: pN0

Number of Lymph Nodes Examined: 17

Number of Lymph Nodes Involved: 0

Distant Metastasis: Not applicable.

Additional Pathologic Findings:

Chronic pancreatitis, extensive.

High grade PanIN.

This case has been reviewed and the diagnoses approved by consulting departmental surgical pathology staff.

[REDACTED]

'The gross description and all microscopic slides have been reviewed and interpreted by the undersigned pathologist'

[REDACTED]

Specimen(s) Received:

A: Liver biopsy

B: Left tube and ovary

C: Falciiform ligament

[page 3 of 7]
Patient Results

Final

D: Peritoneal mass
E: Hepatic duodenal lymph nodes
F: Portal LN
G: Posterior portal LN
H: Anterior portal LN
I: Common Bile Duct
J: Pancreatic margin
K: Whipple's specimen
L: New pancreatic margin
M: Pancreas

Clinical History:
Pancreatic cancer. [REDACTED]
Intraoperative Consultation:
Time Received: [REDACTED]
Time Reported: [REDACTED]

FSA1: Liver biopsy: Benign fibrinosis (1 block).
FSB1: Left tube and ovary7: Mature teratoma (1 block).
FSD1: Peritoneal mass: Benign fibrosis (1 block).
FSI1: Common bile duct: Negative (1 block).
FSJ1: Pancreatic margin: Positive (1 block).
FSL1: New pancreatic margin:
Chronic pancreatitis. Focus suspicious for perineural
tumor at margin (1 block)

Gross Description:

(A) (liver biopsy) Received fresh for intraoperative consultation are two tan-white tissue fragments measuring up to 1.2 cm in greatest dimension and two tan-brown tissue cores measuring up to 1.0 cm in length. The two tan-white tissue fragments are submitted entirely in cassette FSA1. The two tan-brown tissue cores are submitted entirely in cassette A2.
(B) (left tube and ovary) Received fresh for intraoperative consultation is one ovary and fallopian tube measuring as follows: The left fallopian tube measures 4.0 cm in length with an average diameter of 0.5 cm, the left ovary measures 9.5 x 8.0 x 8.0 cm. The surface of the ovary is tan-brown and pink with numerous cystic excrescences measuring up to 1.0 cm in greatest dimension. In addition, several firm, tan-white protruding nodules measuring up to 1.2 cm in greatest dimension are also identified on the surface of the ovary. Opening of the ovary demonstrates soft friable tan-white material admixed with numerous strands of tan-brown hair, smooth interior lining. One rubbery firm nodule adherent to the interior surface measures up to 0.3 cm in greatest dimension. Sectioning of this nodule demonstrates a smooth tan-yellow cut surface without hemorrhage

[page 4 of 7]
Patient Results

Final

or necrosis. The average thickness of the wall measures up to 0.7 cm. A representative section of the wall is submitted in cassette FSB1. The left fallopian tube demonstrates a smooth pink-tan serosa with no identifiable masses or lesions. The fimbriated end is identified and is unremarkable. The remainder of the specimen is submitted as follows:

- B2-B6 - additional sections of ovary
- B7 - fimbriated end submitted entirely
- B8 - distal end of fallopian tube
- B9 - proximal end of fallopian tube

(C) (falciform ligament) Received in formalin is one soft tan-pink, smooth section of tissue with associated soft tan-yellow adipose tissue measuring 7.5 x 2.0 x 1.5 cm. The specimen is soft and rubbery with no identified masses and/or lesions. Representative sections of the specimen are submitted in cassette C1-C3.

(D) (peritoneal mass) Received fresh for intraoperative consultation is one tan-white section of tissue measuring 0.3 x 0.3 x 0.2 cm. The specimen is submitted entirely in cassette FSD1.

(E) (hepatic duodenal lymph nodes) Received in formalin are four tan-brown sections of tissue measuring up to 2.5 cm in greatest dimension with an overall aggregate dimension of 3.0 x 2.5 x 1.5 cm. The specimen is submitted as follows:

- E1 - one lymph node bisected submitted entirely
- E2 - one lymph node bisected submitted entirely
- E3 - one lymph node bisected submitted entirely
- E4 - all remaining tissue submitted entirely

(F) (portal lymph node) Received in formalin is one soft, tan-brown lymph node measuring 1.5 x 1.1 x 0.7 cm. The specimen is bisected and submitted entirely in cassette F1.

(G) (posterior portal lymph node) Received in formalin is one soft, tan-brown lymph node measuring 1.8 x 1.0 x 0.9 cm. The specimen is bisected along the long axis and submitted entirely in cassette G1.

(H) (anterior portal lymph node) Received in formalin is one tan-yellow lymph node measuring 0.7 x 0.5 x 0.4 cm. The specimen is bisected and submitted entirely in cassette H1.

(I) (common bile duct) Received fresh for intraoperative consultation is one circular section of tan-brown tissue measuring 0.9 cm in diameter. The specimen is submitted entirely in cassette I1.

(J) (pancreatic margin) Received fresh for intraoperative consultation is one section of soft tan-white tissue measuring 2.5 x 1.5 x 0.5 cm. The specimen is oriented with one stitch marking the margin of interest. The specimen is bisected and submitted entirely in cassettes FSJ1 and FSJ2.

(K) (Whipple specimen) Received in formalin is one section of

[page 5 of 7]
Patient Results

Final

distal stomach, duodenum, gallbladder with bile duct, and head of pancreas as one intact specimen. The individual components measure as follows: The stomach measures 10.5 x 5.5 x 3.5 cm, the duodenum measures 26.0 cm in length with an average diameter of 2.0 cm, the gallbladder measures 8.0 cm x 2.5 cm x 1.5 cm. The bile duct measures 5.0 cm in length with an average diameter of 0.7 cm, identifiable unremarkable pancreas measures 2.0 x 1.7 x 1.7 cm. Also accompanying the specimen is soft tan-yellow fibroadipose tissue associated with the stomach and proximal duodenum. The serosal surface of the stomach is tan-brown, glistening and smooth with no identifiable masses and/or lesions. Opening of the stomach shows a smooth tan-pink mucosa with no identifiable masses and/or lesions. Opening of the duodenum longitudinally demonstrates a fungating tan-brown, firm lesion centered around the ampulla measuring 3.0 x 2.0 cm. The lesion at the ampulla is approximately 6.0 cm from the pyloric sphincter and greater than 10.0 cm from the distal duodenal resection margin. The remainder of the small bowel mucosa is tan-brown and smooth with no identifiable masses and/or lesions. The serosa of the duodenum is tan-brown, glistening and smooth with no identifiable masses and/or lesions. Approximating the fungating mass at the ampulla and adjacent to the morphologically identifiable pancreas is a firm, well-circumscribed mass measuring 5.0 x 5.0 x 4.5 cm. The serosal surface of the gallbladder is tan-brown, smooth and glistening. Opening of the gallbladder reveals a wall that measures 0.2 cm in thickness. The gallbladder mucosa is yellow-green and velvety. The gallbladder contains yellow-green viscous bile and several soft friable yellow-green stones measuring up to 0.5 cm in greatest dimension. Sectioning of the mass demonstrates a rubbery firm, tan-white cut surface. The specimen is submitted as follows:

- K1-K2 - gastric resection margin, en face
- K3 - representative section of stomach
- K4-K5 - distal duodenal resection margin
- K6 - representative section of duodenum
- K7 - representative sections of gallbladder wall and bile duct
- K8 - uncinate margin
- K9 - section of mass at ampulla to include opening of bile duct
- K10-K12 - full section cut through ampulla, small bowel and head of pancreas
- K13-K14 - additional sections of tumor
- K15 - three lymph nodes submitted entirely
- K16 - one possible lymph node bisected submitted entirely
- K17-K18 - one possible lymph node bisected submitted entirely
- K19 - two possible lymph nodes submitted entirely
- K20 - three possible lymph nodes submitted entirely
- K21 - one possible lymph node submitted entirely

[page 6 of 7]
Patient Results

Final

(L) (new pancreatic margin) Received in formalin is one section of rubbery firm, tan-white nodular tissue measuring 2.5 x 2.0 x 0.9 cm. One black stitch marks the margin of interest.

An en face section at the plane of interest is submitted in cassette FSL1. The margin of interest is inked black. The specimen is sectioned perpendicularly to the margin of interest and representative sections are submitted in cassettes L2-L4.

(M) (pancreas) Received in formalin is one rubbery firm section of tan-yellow pancreas and associated soft tan-yellow adipose tissue measuring 1.5 x 3.0 x 2.5 cm. The surface of the pancreas is tan-yellow and smooth. Two black stitches flank the plane of resection which demonstrates a nodular tan-yellow cut surface. Serial sectioning of the pancreas along the short axis at 0.2 to 0.3 cm intervals demonstrates smooth nodular tan-white cut surface. Representative sections of the specimen are submitted as follows:

M1-M2 - proximal representative sections

M3-M4 - representative sections taken from middle of tail

M5-M6 - representative sections of distal tail

Microscopic Description:

Complete microscopic evaluation has been performed.

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at the

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EFGR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any

[page 7 of 7]
Patient Results

Surgical Pathology (Copath)

Final

proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file 044184d0-5cb7-4734-ab20-d44bc80a881d (TCGA-HZ-7924.803BB8E5-9DA4-4F72-92AE-D7CD4152A665.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).